Surgical pathology report (de-identified scan), TCGA case TCGA-24-2036, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2036-01A (Primary Tumor).

[page 1 of 8]
TCGA-24-2036

DIAGNOSIS

OVARY, RIGHT, ADNEXYCTOMY - POORLY DIFFERENTIATED OVARIAN
ADENOCARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, RIGHT, ADNEXYCTOMY - BENIGN PARATUBAL CYSTS

OMENTUM, OMENTECTOMY - OMENTUM AND FAT WITH NO HISTOPATHOLOGIC
ABNORMALITY
- FIBROUS TISSUE WITH ACUTE INFLAMMATION

SOFT TISSUE, "CUL-DE-SAC NODULE," BIOPSY
- METASTATIC ADENOCARCINOMA

UTERUS, CERVIX, HYSTERECTOMY - ACUTE AND CHRONIC INFLAMMATION
- SQUAMOUS METAPLASIA

UTERUS, ENDOMETRIUM, HYSTERECTOMY - INACTIVE ENDOMETRIUM WITH
NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, MYOMETRIUM, HYSTERECTOMY - ADENOMYOSIS

OVARY, LEFT, SALPINCO-OOPHORECTOMY - NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, LEFT, SALPINCO-OOPHORECTOMY - BENIGN PARATUBAL
CYSTS

LYMPH NODES, LEFT EXTERNAL ILIAC, DISSECTION
- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH
NODES (0/4)

LYMPH NODES, LEFT OBTURATOR, DISSECTION
- NO EVIDENCE OF MALIGNANCY IN FOURTEEN
LYMPH NODES (0/14)

LYMPH NODES, LEFT PARA-AORTIC, DISSECTION
- NO EVIDENCE OF MALIGNANCY IN FIVE
LYMPH NODES (0/5)

[page 2 of 8]
Name:

Surg. Path.

DIAGNOSIS (continued)

LYMPH NODES, RIGHT EXTERNAL ILIAC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5)
- TWO SOFT TISSUE ADENOCARCINOMA METASTASES

LYMPH NODES, RIGHT OBTURATOR, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES (0/9)

LYMPH NODES, RIGHT PARA-AORTIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5)

SOFT TISSUE, LEFT CUTTER, BIOPSY - FIBROFATTY TISSUE WITH ACUTE AND CHRONIC INFLAMMATION AND HEMORRHAGE

SOFT TISSUE, SIGMOID NODULE, BIOPSY - METASTATIC ADENOCARCINOMA
- NECROSIS
- ACUTE AND CHRONIC INFLAMMATION
- GRANULATION TISSUE

DIAPHRAGM, BIOPSY - METASTATIC ADENOCARCINOMA

SOFT TISSUE, RIGHT CUTTER, BIOPSY - FIBROFATTY TISSUE WITH ACUTE INFLAMMATION AND NUMEROUS REACTIVE MESOTHELIAL CELLS

SOFT TISSUE, RIGHT SIDEWALL, BIOPSY - NECROSIS
- ACUTE AND CHRONIC INFLAMMATION

SOFT TISSUE, LEFT SIDEWALL, BIOPSY - NECROSIS
- ACUTE INFLAMMATION

[page 3 of 8]
Name:

Surg. Path. No.:

SPECIMEN(S) SUBMITTED

- Part 1: FS1-RIGHT ADNEXA
- Part 2: X-RIGHT ADEXA
- Part 3: OMENTUM
- Part 4: CUL-DE-SAC
- Part 5: UTERUS, CERVIX, LEFT ADNEXA
- Part 6: LEFT EXTERNAL ILIAC LYMPH NODE
- Part 7: LEFT OBTURATOR LYMPH NODE
- Part 8: LEFT PERI-AORTIC LYMPH NODE
- Part 9: RIGHT EXTERNAL ILIAC LYMPH NODE
- Part 10: RIGHT OBTURATOR LYMPH NODE
- Part 11: RIGHT PERI-AORTIC LYMPH NODE
- Part 12: LEFT CUTTER
- Part 13: SIGMOID NODULE
- Part 14: DIAPHRAGM
- Part 15: RIGHT CUTTER
- Part 16: RIGHT SIDEWALL
- Part 17: LEFT SIDEWALL

HISTORY

The patient is a [REDACTED] with a history of breast cancer [REDACTED] (node negative; treated with chemotherapy and radiation therapy). The patient now presents with a right adnexal mass and pleural effusion. Operative procedure: Not stated, but appears to be right adnexectomy followed by hysterectomy and left salpingo-oophorectomy as well as staging with multiple lymph node dissections and intra-abdominal biopsies. Clinical diagnosis: Right adnexal mass and pleural effusion with a remote history of breast cancer.

FROZEN

Right adnexa - "Mullerian neoplasm" of at least low malignant potential, [REDACTED]

[page 4 of 8]
Name:

Surg. Path. No.:

GROSS

The specimens are received in 17 containers of formalin, each labelled with the patient's name. The first is labelled "FS" and contains one fragment of white-tan tissue, measuring 1.8 x 1.7 x 0.2 cm. [REDACTED]

The second container is labelled "X, #2, right adnexa." It contains four fragments of tissue, one of which is an 11.5 x 11.0 x 9.0 cm., tan, partly papillary, but mostly necrotic mass. The other three fragments appear to have come from the mass and in aggregate measure 4.5 x 4.8 x 1.5 cm. No cystic areas are seen in any of the fragments. All four fragments in aggregate weigh 441.2 grams. Grossly no normal ovary is seen although one of the fragments separate from the tumor mass is a potential candidate; this fragment of brown-tan tissue measures 2.7 x 1.2 x 2.1 cm. A 2.0 cm. long, tube-shaped structure with a greatest cylindrical diameter of 0.9 cm. is seen. This grossly is suggestive of a fallopian tube. CPT. Labelled XA-XF with XA-XD being apparent tumor, XE being possible normal ovary, and XF being three sections of possible fallopian tube. [REDACTED]

The third container is labelled "#1, omentum" and contains two separate fragments of fatty tissue, one of which looks more like classical omentum with the other (the smaller) appearing more like pericolic fat. The larger fragment, which looks more like omentum, measures 30.0 x 15.0 x 2.0 cm. The separate smaller fragment, which appears more like pericolic fat, measures 10.5 x 5.5 x 1.5 cm. Labelled A1-A5, sections of what grossly appears to be omentum; A6, section of separate fragment fat that grossly appears more consistent with pericolic fat. [REDACTED]

The fourth container is labelled "#3, cul-de-sac nodule." It contains eleven fragments of tissue, some of which appear to be clot, the remainder is firm, white-tan-brown tissue. In aggregate the specimen measures 5.0 x 5.2 x 1.5 cm. [REDACTED]

The fifth container is labelled "#4, uterus, cervix, LSO." It contains a hysterectomy specimen consisting of corpus and cervix with attached left ovary and left fallopian tube. The 94.4 gram uterus measures 8.2 cm. superoinferiorly by 4.5 cm. medial-laterally by 4.0 cm. anteroposteriorly. The ectocervix

[page 5 of 8]
[REDACTED]

Name: [REDACTED]

Surg. Path. No.: [REDACTED]

CROSS (continued)

measures 3.3 cm. medial-laterally by 3.5 cm. anteroposteriorly. The endocervical canal is 5.0 cm. long. The endometrial cavity measures 2.0 cm. medial-laterally by 2.3 cm. superoinferiorly. A 1.5 cm. subserosal discrete, firm, white, whorled lesion without necrosis is seen in the posterior corpus. No other abnormalities of the uterus are seen. The grossly normal left ovary measures 1.8 x 0.8 x 0.8 cm. The 3.5 cm. long fallopian tube has a greatest cylindrical diameter of 0.8 cm. Four apparent benign paratubal cysts are seen, each with greatest dimension varying from 0.1 to 0.6 cm. Labelled C1, anterior cervix; C2, posterior cervix; E1, anterior endomyometrium; E2, posterior endomyometrium; M, putative leiomyoma; LO, left ovary; LT, two transverse sections of left fallopian tube along with the largest apparent benign paratubal cyst. [REDACTED]

The sixth container is labelled "#5, left external iliac lymph node." It contains one fragment of partly soft, yellow, fatty tissue but also partly firm, brown tissue. The fragment measures 3.8 x 2.2 x 1.5 cm. [REDACTED]

The seventh container is labelled "#6, left obturator lymph node." It contains one fragment of partly soft, yellow, fatty tissue in which is intermixed firm, brown tissue. The fragment measures 4.5 x 3.2 x 1.5 cm. [REDACTED]

The eighth container is labelled "#7, left para-aortic lymph node." It contains three fragments of mostly soft, yellow, fatty tissue in which is intermixed firm, brown tissue. The fragments in aggregate measure 2.0 x 1.8 x 0.8 cm. [REDACTED]

The ninth container is labelled "#8, right external iliac lymph node." It contains five fragments of soft, yellow, fatty tissue with which is intermixed firm, tan and white tissue. In aggregate the specimen measures 4.0 x 3.0 x 2.0 cm. [REDACTED]

The tenth container is labelled "#9, right obturator lymph node." It contains seven fragments of partly soft, yellow, fatty tissue with which is intermixed firm, brown-tan tissue. In aggregate the fragments measure 5.0 x 3.5 x 2.5 cm. [REDACTED]

The eleventh container is labelled "#10, right para-aortic lymph

[page 6 of 8]
CROSS (continued)

node." It contains one fragment of mostly soft, yellow, fatty tissue measuring 3.8 x 1.5 x 1.2 cm. [REDACTED]

The twelfth container is labelled "#11, left gutter biopsy." It contains one fragment of soft, tan tissue measuring 1.3 x 0.4 x 0.4 cm. [REDACTED]

The thirteenth container is labelled "#12, sigmoid nodule." It contains two fragments of white and brown tissue, in aggregate measuring 1.4 x 1.4 x 0.4 cm. [REDACTED]

The fourteenth container is labelled "#13, diaphragm biopsy." It contains one fragment of white tissue, measuring 0.7 x 0.4 x 0.2 cm. Marked with hematoxylin and wrapped. [REDACTED]

The fifteenth container is labelled "#14, right gutter biopsy." It contains one fragment of firm, yellow and brown tissue, measuring 0.7 x 0.5 x 0.4 cm. [REDACTED]

The sixteenth container is labelled "#15, right sidewall biopsy." It contains one fragment of L-shaped, brown tissue, measuring 1.2 x 0.8 x 0.3 cm. [REDACTED]

The seventeenth container is labelled "#16, left sidewall biopsy." It contains one fragment of brown and tan tissue, measuring 0.7 x 0.5 x 0.3 cm. [REDACTED]

COMMENT

The poorly differentiated ovarian adenocarcinoma is predominantly of a papillary serous pattern; however, portions of the adenocarcinoma have an endometrioid pattern. The metastases seen show an adenocarcinoma with histology identical to the primary adenocarcinoma of the right ovary.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Adenocarcinoma, see comment

[page 7 of 8]
Name:

Surg. Path. No.

COMMENT (continued)

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right ovary only
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. The presence of tumor invasion of the mesovarium CANNOT BE EVALUATED.
8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED.
9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT.
12. Metastatic involvement of the omentum is ABSENT.
13. Metastatic involvement of the uterine serosa is ABSENT.
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases are ABSENT, although two soft tissue metastases are present in the right external iliac lymph node dissection.
16. The total number of regional lymph nodes examined is 42
17. The total number of metastatically-involved regional lymph nodes is 0.
Extranodal extension by tumor is NOT APPLICABLE; no

[page 8 of 8]
Name:

Surg. Path.

COMMENT (continued)

nodal metastases are present

18. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME
T3a

FIGO SCHEME
IIIA

DEFINITION
Microscopic peritoneal
metastasis beyond true pelvis

THE REGIONAL LYMPH NODES are classified as:
N0 (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as:
M0 (Distant metastases are reportedly absent)

19. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME
3a

(T3a/ N0/ M0)

FIGO SCHEME
IIIA

(End of Report)

Source: NCI Genomic Data Commons file 6b0fa658-4f05-4a1a-ab1b-ceacc09705d8 (TCGA-24-2036.3C1ECC69-A121-4C32-B15A-1E5BBF2F8D7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).